Somatic mutation profile of tumor specimen TCGA-HT-A5R5-01A (aliquot TCGA-HT-A5R5-01A-11D-A289-08) from TCGA case TCGA-HT-A5R5, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.0 years (12,403 days).
Specimen TCGA-HT-A5R5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72f72669-fe37-4df2-8b5b-025ae3d9f91d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5R5-10A (Blood Derived Normal), aliquot TCGA-HT-A5R5-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51a435bd-0cbf-4df6-83fa-53f7ed26b653

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/31 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ATRX | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV64878137, COSV64881096; called by muse, mutect2, varscan2
- BTAF1 | c.2703A>G p.I901M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV56437662; called by muse, mutect2, varscan2
- CIP2A | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868551176, COSV55420579; called by muse, mutect2
- CTCF | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV50482681; called by muse, mutect2, varscan2
- DCHS1 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139750490; called by muse, mutect2, varscan2
- GAB3 | c.1719C>G p.S573R | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV65818758, COSV65820453; called by muse, mutect2
- HARS1 | c.32T>A p.V11E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56908700; called by muse, varscan2
- KRI1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57263692, COSV57265500; called by muse, mutect2, varscan2
- LHFPL4 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV55004082; called by muse, mutect2
- NLRP8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149738419; called by muse, mutect2, varscan2
- NUAK1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54606733, COSV54608387; called by muse, mutect2
- PLEKHM3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66818158; called by muse, mutect2, varscan2
- PLEKHO1 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV50311041; called by muse, mutect2
- PRSS35 | c.94A>T p.R32* | Nonsense Mutation (SNP) | VAF 11/126 reads (9%) | catalogued as COSV63801054; called by muse, mutect2
- PTK2B | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57763204; called by muse, mutect2
- RORB | c.925+1G>T p.X309_splice (on ENST00000396204 / NM_001365023.1; = p.X298_splice on NM_006914.4) | Splice Site (SNP) | VAF 14/91 reads (15%) | catalogued as COSV65338807; called by muse, mutect2, varscan2
- SCTR | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV50030423; called by muse, mutect2
- TECTA | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV50769419; called by muse, mutect2
- TFRC | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64055946; called by muse, mutect2, varscan2
- PLXNA4 | c.5214_5220del p.W1738* | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- C7 | c.1074C>T p.N358= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs147954006, COSV57477368; called by muse, mutect2, varscan2
- DMD | c.7614A>G p.K2538= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV58937796; called by muse, mutect2, varscan2
- FBXO30 | c.1194T>C p.S398= | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as COSV52792040; called by muse, mutect2, varscan2
- IGSF22 | c.963C>T p.L321= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV60037272; called by muse, mutect2, varscan2
- MTREX | c.3114C>T p.A1038= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1180657957, COSV53307159; called by muse, mutect2
- NUCB1 | c.900G>T p.V300= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV54387663; called by muse, mutect2
- STRAP | c.723C>T p.G241= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs759466450, COSV50309015; called by muse, mutect2, varscan2
- TRHR | c.399C>G p.A133= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV61235372, COSV61235888; called by muse, mutect2, varscan2
